Somatic mutation profile of tumor specimen TCGA-HU-A4GU-01A (aliquot TCGA-HU-A4GU-01A-11D-A25D-08) from TCGA case TCGA-HU-A4GU, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 74.0 years (27,024 days).
Specimen TCGA-HU-A4GU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c04f0c00-79a2-4784-8979-b905bbbac37a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4GU-10A (Blood Derived Normal), aliquot TCGA-HU-A4GU-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8565cc42-b20d-486c-a323-3e2d206ac324

The open-access MAF lists 1,695 somatic variants for this specimen: 1,242 protein-altering or splice-affecting, 417 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 941, Silent 417, Frame Shift Del 200, Nonsense Mutation 45, Frame Shift Ins 32, Intron 19, Splice Site 14, Splice Region 8, 3'UTR 5, RNA 4, 3'Flank 3, 5'Flank 3.

Variants (750 of 1,695; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.1801C>T p.R601* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as rs772229371, COSV56357972; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGEF10L | c.3646G>A p.D1216N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs149908903, CM166326, COSV51429967; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARSA | c.418dup p.H140Pfs*36 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | catalogued as rs745884435; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BLM | c.2875C>T p.R959* | Nonsense Mutation (SNP) | VAF 36/126 reads (29%) | catalogued as rs762354041, COSV61922766; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLNA | c.1923C>T p.G641= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs80338841, CS062053, COSV61040235; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNPTAB | c.2956C>T p.R986C | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769587233, CM123166, COSV54778214; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GRM1 | c.26del p.F9Sfs*119 | Frame Shift Del (DEL) | VAF 65/190 reads (34%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- HNF1A | c.1129del p.L377Sfs*7 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | catalogued as rs193922576; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ISCA2 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882246, CM151129, COSV53143122; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 6/24 reads (25%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- MYO7A | c.1623dup p.K542Qfs*5 | Frame Shift Ins (INS) | VAF 40/172 reads (23%) | catalogued as rs782077721; ClinVar: pathogenic; called by mutect2, varscan2
- PAX2 | c.76dup p.V26Gfs*28 | Frame Shift Ins (INS) | VAF 13/52 reads (25%) | catalogued as rs75462234; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SGCB | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 6/134 reads (4%) | catalogued as rs1013015106, COSV67340757; ClinVar: pathogenic; called by muse, mutect2
- SLC12A1 | c.1163del p.F388Sfs*40 | Frame Shift Del (DEL) | VAF 28/117 reads (24%) | catalogued as rs779588655; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SLCO2A1 | c.830del p.F277Sfs*8 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | catalogued as rs751192029; ClinVar: pathogenic; called by mutect2, varscan2
- SPRED1 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as rs121434315, CM074582, COSV54435140; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRIP11 | c.1622del p.K541Rfs*17 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | catalogued as rs1420691965; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2ML1 | c.2557A>C p.T853P | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1448293204, COSV100229382; called by muse, mutect2, varscan2
- AAR2 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.125); catalogued as rs375933541; called by muse, mutect2, varscan2
- AASDH | c.1319del p.L440Wfs*43 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | catalogued as rs770970036; called by mutect2, varscan2
- ABCA1 | c.4219G>A p.A1407T | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as rs189206655, COSV66064966; called by muse, mutect2, varscan2
- ABCB5 | c.2899G>A p.A967T (on ENST00000404938 / NM_001163941.2; = p.A522T on NM_178559.6) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV51706104; called by muse, varscan2
- ABCC1 | c.4528G>A p.A1510T | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs764004869, COSV60682736; called by muse, mutect2, varscan2
- ABCC4 | c.3655del p.I1219Sfs*11 | Frame Shift Del (DEL) | VAF 58/89 reads (65%) | catalogued as rs756859429, COSV65316407; called by mutect2, varscan2
- ABCC6 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.224); catalogued as rs776248626, COSV52742326; called by muse, mutect2, varscan2
- ABCG8 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.724); catalogued as rs781662653, COSV55391634; called by muse, mutect2, varscan2
- ABHD16A | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV65451532; called by muse, mutect2, varscan2
- ABLIM1 | c.29T>G p.L10R | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.034); catalogued as COSV65099653; called by muse, mutect2, varscan2
- AC126283.2 | c.1326del p.D443Ifs*49 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | catalogued as rs1366136808; called by mutect2, pindel, varscan2
- ACADM | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1431463788, COSV57714280; called by muse, mutect2, varscan2
- ACADSB | c.534G>T p.E178D | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62550502; called by muse, mutect2, varscan2
- ACMSD | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV51606305; called by muse, mutect2, varscan2
- ACTB | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV59317153, COSV59317683; called by muse, mutect2, varscan2
- ACTR6 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375164278, COSV51842902; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 34/68 reads (50%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVRL1 | c.1105A>G p.R369G | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66359832; called by muse, mutect2
- ADAM2 | c.872A>G p.Y291C | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV55860279; called by muse, mutect2, varscan2
- ADAM22 | c.991del p.S331Rfs*22 | Frame Shift Del (DEL) | VAF 14/103 reads (14%) | catalogued as rs34958294; called by mutect2, pindel, varscan2
- ADAM30 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.684); catalogued as COSV65560669; called by muse, mutect2, varscan2
- ADAMTS12 | c.4523A>G p.D1508G | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV61259123, COSV61262746; called by muse, mutect2, varscan2
- ADAMTS12 | c.2402T>G p.V801G | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV61259142; called by muse, mutect2, varscan2
- ADAMTS12 | c.1266G>T p.Q422H | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61259151; called by muse, mutect2, varscan2
- ADAMTS3 | c.2662G>A p.A888T | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV54388065; called by muse, mutect2, varscan2
- ADAMTS3 | c.1696A>G p.T566A | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV54388078; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2341C>T p.R781C | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs149442347; called by muse, varscan2
- ADARB1 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.59); catalogued as COSV62343072; called by muse, mutect2, varscan2
- ADCY3 | c.2653C>T p.R885* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | catalogued as COSV53165881; called by muse, mutect2, varscan2
- ADCY7 | c.2573C>T p.A858V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54265344; called by muse, mutect2, varscan2
- ADCY9 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV53573279; called by muse, mutect2, varscan2
- ADGRB3 | c.2971C>A p.P991T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53235067, COSV53239260; called by muse, mutect2, varscan2
- ADGRG5 | c.608del p.G203Afs*62 | Frame Shift Del (DEL) | VAF 21/69 reads (30%) | catalogued as rs750862917; called by mutect2, pindel, varscan2
- ADGRL2 | c.4133T>G p.L1378R (on ENST00000370717 / NM_001366005.1; = p.L1322R on NM_012302.4) | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54659909; called by muse, mutect2, varscan2
- ADGRV1 | c.17107C>T p.R5703C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs761963239, COSV67981620; called by muse, mutect2, varscan2
- ADM | c.530dup p.S178Efs*19 | Frame Shift Ins (INS) | VAF 23/56 reads (41%) | catalogued as rs773405081; called by mutect2, varscan2
- ADRA1B | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV60700586, COSV60701089; called by muse, mutect2
- AEBP1 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs150909656; called by muse, mutect2
- AFAP1 | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV61794502, COSV61794718; called by muse, mutect2, varscan2
- AFDN | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV60041076; called by muse, mutect2, varscan2
- AFG1L | c.750T>A p.D250E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV64554817, COSV64555110; called by muse, mutect2, varscan2
- AGAP1 | c.1984C>T p.R662* (on ENST00000304032 / NM_001037131.3; = p.R609* on NM_014914.5) | Nonsense Mutation (SNP) | VAF 24/94 reads (26%) | catalogued as COSV58321552; called by muse, mutect2, varscan2
- AGBL1 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs778802190, COSV69794057; called by muse, mutect2, varscan2
- AGL | c.2234C>A p.A745D | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV54050459; called by muse, mutect2, varscan2
- AGL | c.4580A>G p.E1527G | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54050485; called by muse, mutect2, varscan2
- AHNAK | c.14323G>A p.D4775N | Missense Mutation (SNP) | VAF 72/301 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV57208318; called by muse, mutect2, varscan2
- AHNAK2 | c.2392A>G p.S798G | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.304); catalogued as COSV60911395; called by muse, varscan2
- AIDA | c.641A>G p.E214G | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs560922639, COSV100388302; called by muse, mutect2, varscan2
- AIFM3 | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV58998334; called by muse, mutect2, varscan2
- AK1 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs780530648, COSV56344907; called by muse, mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs778351035; called by pindel, varscan2
- AKAP11 | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367790495; called by muse, mutect2, varscan2
- AKAP11 | c.5264T>C p.L1755P | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50294498; called by muse, mutect2, varscan2
- AKAP13 | c.6598C>T p.R2200C (on ENST00000394518 / NM_007200.5; = p.R2204C on NM_006738.6) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63450117; called by muse, mutect2
- AKAP8 | c.1451G>A p.C484Y | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54101761; called by muse, mutect2, varscan2
- AKAP9 | c.5862C>T p.G1954= (on ENST00000359028; = p.G1922= on NM_005751.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 16/270 reads (6%) | catalogued as rs781051056, COSV62342079; called by muse, mutect2
- AKR7A2 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV52515985; called by muse, mutect2, varscan2
- ALDH16A1 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); catalogued as COSV52618667; called by muse, mutect2
- ALDH2 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs200738174, COSV55666013; called by muse, mutect2, varscan2
- ALDH3B2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1140670, COSV62427836; called by muse, mutect2, varscan2
- ALDH5A1 | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs754091433, COSV62373108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG10 | c.438del p.F146Lfs*20 | Frame Shift Del (DEL) | VAF 21/95 reads (22%) | catalogued as rs1163730964; called by mutect2, pindel, varscan2
- ALK | c.2827G>A p.A943T | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV66562470; called by muse, mutect2, varscan2
- ALKBH7 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs769699986, COSV55531973; called by muse, mutect2, varscan2
- AMER1 | c.905A>G p.N302S | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs1235049855, COSV57657126; called by muse, mutect2
- AMOTL2 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs372900931; called by muse, mutect2, varscan2
- AMPD3 | c.1420C>T p.P474S (on ENST00000396553 / NM_001025389.2; = p.P483S on NM_000480.3) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67330361; called by muse, mutect2, varscan2
- AMY2B | c.181A>T p.N61Y | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV63714700; called by muse, mutect2, varscan2
- ANAPC1 | c.4747G>A p.A1583T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs760585060, COSV61975107; called by muse, mutect2, varscan2
- ANGPTL3 | c.1297T>C p.S433P | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV52000438; called by muse, mutect2, varscan2
- ANKRD11 | c.3467G>T p.R1156L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV56357961; called by muse, mutect2, varscan2
- ANO3 | c.2395C>T p.R799W | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56779997; called by muse, mutect2, varscan2
- ANO4 | c.881C>T p.A294V (on ENST00000392977 / NM_001286615.2; = p.A259V on NM_178826.4) | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1258502826, COSV54590058; called by muse, mutect2
- ANOS1 | c.482A>C p.K161T | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52916948, COSV52917470; called by muse, mutect2, varscan2
- ANTXR1 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs370351341, COSV58009335; called by muse, mutect2, varscan2
- AOC2 | c.2249del p.P750Lfs*58 (on ENST00000253799 / NM_009590.4; = p.P723Lfs*58 on NM_001158.5) | Frame Shift Del (DEL) | VAF 56/310 reads (18%) | catalogued as rs34587880; called by mutect2, varscan2
- AP1G2 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs142884247; called by muse, mutect2, varscan2
- AP1M1 | c.440del p.P147Rfs*90 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as COSV52226362; called by mutect2, pindel, varscan2
- AP2A2 | c.212A>G p.D71G | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV59958998; called by muse, mutect2, varscan2
- AP5M1 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV55104893; called by muse, mutect2, varscan2
- APC | c.4364dup p.N1455Kfs*2 | Frame Shift Ins (INS) | VAF 46/78 reads (59%) | catalogued as COSV57364337; called by mutect2, pindel, varscan2
- APH1B | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0.02); catalogued as COSV56013968; called by muse, mutect2, varscan2
- APOA4 | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 60/96 reads (63%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.911); catalogued as COSV63360245; called by muse, mutect2, varscan2
- APOB | c.3808G>T p.D1270Y | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV51929483; called by muse, mutect2, varscan2
- APP | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.292); catalogued as COSV60996360; called by muse, mutect2, varscan2
- AQP10 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.041); catalogued as COSV61474672; called by muse, mutect2, varscan2
- AR | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.944); catalogued as COSV65954491; called by muse, mutect2, varscan2
- ARHGAP31 | c.3649C>T p.P1217S | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as rs767879882, COSV51790832; called by muse, mutect2, varscan2
- ARHGEF11 | c.2420A>G p.K807R | Missense Mutation (SNP) | VAF 144/275 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV59353100; called by muse, mutect2, varscan2
- ARID1A | c.6147del p.W2049Cfs*86 | Frame Shift Del (DEL) | VAF 27/139 reads (19%) | catalogued as COSV61372385; called by mutect2, pindel, varscan2
- ARID4A | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs770373766, COSV62162543; called by mutect2, varscan2
- ARID4A | c.1266del p.D423Tfs*2 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs776520069; called by mutect2, varscan2
- ARIH1 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV65911041; called by muse, mutect2, varscan2
- ARL11 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 48/66 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV56290875; called by muse, mutect2, varscan2
- ARMCX3 | c.603A>T p.K201N | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57870019; called by muse, mutect2, varscan2
- ARSG | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs150072981, COSV71593277; called by muse, mutect2, varscan2
- ASB4 | c.530C>T p.T177M | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57943938; called by muse, mutect2, varscan2
- ASH1L | c.2148A>C p.K716N | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV64206634; called by muse, mutect2, varscan2
- ASIC2 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765631881, COSV56758247; called by muse, mutect2, varscan2
- ASPM | c.6674C>A p.A2225E | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54127326; called by muse, mutect2, varscan2
- ASTL | c.215T>G p.F72C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60903829; called by muse, mutect2, varscan2
- ASXL3 | c.3257C>T p.A1086V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.419); catalogued as COSV52461656; called by muse, mutect2, varscan2
- ATP13A4 | c.3020G>A p.C1007Y | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV61318055; called by muse, mutect2, varscan2
- ATP2B1 | c.2536C>T p.R846* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as COSV53805755, COSV53811872; called by muse, mutect2, varscan2
- ATP4A | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52866824; called by muse, mutect2, varscan2
- AUTS2 | c.2593G>T p.A865S | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV61390601; called by muse, mutect2, varscan2
- AXIN1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as rs753659585, COSV51985350; called by muse, mutect2, varscan2
- B4GALNT1 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.753); catalogued as COSV57542071; called by muse, mutect2, varscan2
- B4GALT2 | c.21del p.T8Rfs*102 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as rs759490732, COSV99356264; called by mutect2, pindel, varscan2
- B4GALT5 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.96); catalogued as rs752406119, COSV65493160; called by muse, mutect2, varscan2
- B4GALT7 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.037); catalogued as COSV50352592; called by muse, mutect2, varscan2
- BAZ1A | c.3446C>T p.A1149V | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV62409629; called by muse, mutect2, varscan2
- BCAT2 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751932058, COSV60272159; called by muse, mutect2, varscan2
- BCHE | c.1453A>G p.T485A | Missense Mutation (SNP) | VAF 48/70 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV52254861; called by muse, mutect2, varscan2
- BCKDK | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as rs755584594, COSV54891042; called by muse, mutect2, varscan2
- BCL11A | c.1231G>A p.A411T (on ENST00000335712 / NM_001365609.1; = p.A445T on NM_018014.4) | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs745490013, COSV100184710, COSV59626834; called by muse, mutect2, varscan2
- BCL2L2 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.071); catalogued as rs746534702, COSV51635702; called by muse, mutect2, varscan2
- BCL9L | c.2401C>T p.R801W | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs866249341, COSV52683035; called by muse, mutect2, varscan2
- BCL9L | c.1478del p.P493Rfs*9 | Frame Shift Del (DEL) | VAF 37/299 reads (12%) | catalogued as COSV52683193; called by mutect2, pindel, varscan2
- BCL9L | c.1354del p.Q452Sfs*11 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | catalogued as rs756382429; called by pindel, varscan2
- BEST2 | c.1052C>A p.T351N | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV50366952; called by muse, mutect2, varscan2
- BMP3 | c.1079G>T p.R360M | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51082284; called by muse, mutect2, varscan2
- BMS1 | c.2650A>G p.M884V | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs2419109; called by muse, mutect2, varscan2
- BPIFB4 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs143050216; called by muse, mutect2, varscan2
- BPIFB6 | c.398A>C p.K133T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.089); catalogued as COSV62754721; called by muse, mutect2, varscan2
- BPTF | c.6572G>C p.R2191T | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58830586; called by muse, mutect2, varscan2
- BRCA2 | c.7617G>T p.Q2539H | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1442441018, COSV66450915; called by muse, mutect2, varscan2
- BRD1 | c.1657-2A>C p.X553_splice | Splice Site (SNP) | VAF 5/25 reads (20%) | catalogued as COSV53455866; called by muse, mutect2, varscan2
- BTBD17 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100945344; called by muse, mutect2
- BTBD7 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs143569452; called by muse, mutect2, varscan2
- BUD23 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs781951178, COSV56094535; called by muse, mutect2
- C10orf120 | c.543G>T p.Q181H | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV61491761, COSV61492612; called by muse, mutect2, varscan2
- C12orf50 | c.1097A>T p.N366I | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.332); catalogued as COSV53894222; called by muse, mutect2, varscan2
- C17orf97 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs782749502, COSV64076188; called by muse, mutect2, varscan2
- C1QC | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.145); catalogued as rs772221556, COSV65889392; called by muse, mutect2, varscan2
- C3AR1 | c.1354G>T p.G452* | Nonsense Mutation (SNP) | VAF 25/131 reads (19%) | catalogued as COSV50817777, COSV50818332; called by muse, mutect2, varscan2
- C5 | c.4603A>G p.M1535V | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV56325577; called by muse, mutect2, varscan2
- C5orf38 | c.364C>A p.L122M | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as rs1314815348, COSV57410452; called by muse, mutect2, varscan2
- C7orf25 | c.242A>C p.N81T | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.266); catalogued as COSV63273372; called by muse, mutect2, varscan2
- C7orf26 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.358); catalogued as rs565936469, COSV60418284; called by muse, mutect2, varscan2
- C8B | c.428A>G p.D143G | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761727726, COSV64777130; called by muse, mutect2, varscan2
- C9 | c.185T>A p.F62Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.193); catalogued as COSV54675414; called by muse, mutect2, varscan2
- CA4 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs777463944, COSV56281014; called by muse, mutect2, varscan2
- CABIN1 | c.6227C>T p.P2076L | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV54079745; called by muse, mutect2, varscan2
- CACNA1C | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104404676, COSV59706212; called by muse, mutect2
- CACNA2D3 | c.566T>G p.V189G | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55525455; called by muse, mutect2, varscan2
- CACNB1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs867833158, COSV100703605, COSV59998410; called by muse, mutect2, varscan2
- CACNG5 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1333562967, COSV50055154; called by muse, mutect2, varscan2
- CAD | c.4846G>A p.A1616T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.61); catalogued as rs767360656, COSV53024989; called by muse, mutect2, varscan2
- CAMKV | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV56554677; called by muse, mutect2, varscan2
- CARMIL3 | c.2615G>A p.C872Y | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs761097749, COSV57725588; called by muse, mutect2, varscan2
- CASP5 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.027); catalogued as rs1397399939, COSV52827519; called by muse, mutect2, varscan2
- CAST | c.1217C>T p.A406V (on ENST00000341926; = p.A489V on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.052); catalogued as COSV57784189; called by muse, mutect2, varscan2
- CATSPER1 | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1421729194; called by muse, mutect2
- CATSPER4 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs370751508; called by muse, mutect2, varscan2
- CATSPERE | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780686998, COSV63676966, COSV63680750; called by muse, mutect2, varscan2
- CAV2 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV56063693, COSV56064421; called by mutect2, varscan2
- CBFA2T3 | c.1631C>T p.T544M | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs751448990, COSV51925070; called by muse, mutect2, varscan2
- CC2D2A | c.4609dup p.S1537Kfs*9 | Frame Shift Ins (INS) | VAF 9/34 reads (26%) | catalogued as rs1259255310; called by mutect2, pindel, varscan2
- CCDC151 | c.419C>A p.P140Q | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV52950819; called by muse, mutect2, varscan2
- CCDC171 | c.721T>A p.L241I | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV52638009; called by muse, mutect2
- CCDC180 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as rs151161375; called by muse, mutect2, varscan2
- CCDC185 | c.1304T>G p.V435G | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV64820545; called by muse, mutect2, varscan2
- CCDC42 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs376369221; called by muse, mutect2, varscan2
- CCDC68 | c.852G>T p.K284N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV61603327; called by muse, mutect2, varscan2
- CCDC80 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52814717; called by muse, mutect2, varscan2
- CCDC83 | c.840A>C p.E280D (on ENST00000342404 / NM_001286159.2; = p.E311D on NM_173556.5) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV54700889; called by muse, mutect2, varscan2
- CCKBR | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777692103, COSV58099117, COSV58099888; called by muse, mutect2, varscan2
- CCM2 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs762020337, COSV51847362; called by muse, mutect2, varscan2
- CCNJL | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV57444015; called by muse, mutect2, varscan2
- CCR7 | c.904A>G p.K302E | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.566); catalogued as rs1468121375, COSV55848927; called by muse, mutect2, varscan2
- CCT7 | c.1009C>A p.L337M | Missense Mutation (SNP) | VAF 76/305 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.394); catalogued as COSV54583081; called by muse, mutect2, varscan2
- CD1E | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV100937010, COSV63770217; called by muse, mutect2, varscan2
- CD207 | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.19); catalogued as rs1441117520, COSV69651882; called by muse, mutect2, varscan2
- CD300LB | c.276G>T p.E92D | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as COSV58725370; called by muse, mutect2, varscan2
- CD44 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs989971374, COSV53533293; called by muse, mutect2, varscan2
- CD93 | c.1214G>A p.G405D | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55664188; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 22/94 reads (23%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC40 | c.1506del p.F502Lfs*6 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as COSV57009608; called by mutect2, pindel, varscan2
- CDC42BPG | c.3467G>A p.R1156H | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.153); catalogued as rs760698253, COSV61346322; called by muse, mutect2, varscan2
- CDC42EP1 | c.289dup p.R97Pfs*78 | Frame Shift Ins (INS) | VAF 13/74 reads (18%) | catalogued as rs762035931; called by mutect2, varscan2
- CDH11 | c.1044G>C p.E348D | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); catalogued as COSV51755949; called by muse, mutect2, varscan2
- CDH23 | c.2741C>T p.A914V | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.832); catalogued as COSV54928523; called by muse, mutect2
- CDK18 | c.164del p.P55Rfs*38 (on ENST00000506784 / NM_212503.3; = p.P55Rfs*91 on NM_002596.4) | Frame Shift Del (DEL) | VAF 4/9 reads (44%) | catalogued as rs753136425; called by mutect2, varscan2
- CDRT4 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146969230; called by muse, mutect2, varscan2
- CELF5 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as rs779765913, COSV53010905; called by muse, mutect2, varscan2
- CELSR1 | c.5041G>A p.G1681R | Missense Mutation (SNP) | VAF 96/174 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355852186, COSV53086324; called by muse, mutect2, varscan2
- CELSR2 | c.7981G>A p.D2661N | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.304); catalogued as COSV54768884; called by muse, mutect2, varscan2
- CEP112 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs147020220, COSV67137724; called by muse, mutect2, varscan2
- CEP192 | c.2867G>A p.R956H | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs752095796, COSV58061853; called by muse, mutect2, varscan2
- CEP250 | c.7318G>A p.A2440T | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs748792917, COSV61168911; called by muse, mutect2, varscan2
- CFAP61 | c.2365C>A p.L789M | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.837); catalogued as COSV55623667; called by muse, mutect2, varscan2
- CFHR3 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV66401818; called by muse, mutect2, varscan2
- CGAS | c.433G>C p.G145R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs373045600, COSV64807932; called by muse, mutect2
- CHD2 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV59119467; called by muse, mutect2, varscan2
- CHD2 | c.4352G>A p.S1451N | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.954); catalogued as COSV67707713; called by muse, mutect2, varscan2
- CHD6 | c.4003G>A p.E1335K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV58555498; called by muse, mutect2, varscan2
- CHIA | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs373325850; called by muse, varscan2
- CHL1 | c.3337+2T>C p.X1113_splice (on ENST00000397491 / NM_001253387.1; = p.X1129_splice on NM_006614.4) | Splice Site (SNP) | VAF 7/52 reads (13%) | catalogued as COSV56589619; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | catalogued as rs751548647; called by mutect2, varscan2
- CHST1 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1333206256, COSV57322764; called by muse, mutect2, varscan2
- CIC | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.351); catalogued as COSV50554096; called by muse, mutect2, varscan2
- CIITA | c.1962del p.A656Pfs*30 | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | catalogued as COSV60863473; called by mutect2, pindel, varscan2
- CIITA | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs143801818; called by muse, mutect2, varscan2
- CLDN17 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 60/81 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as rs773823219, COSV54522581, COSV99729023; called by muse, mutect2, varscan2
- CLEC1A | c.265A>G p.M89V | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV59531369; called by muse, mutect2, varscan2
- CLEC4M | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs370560578, COSV50217617; called by muse, mutect2, varscan2
- CLIC2 | c.10C>A p.L4M | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.05); catalogued as COSV58935964, COSV58938369; called by muse, mutect2, varscan2
- CLIP1 | c.893G>C p.R298P | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV100211420, COSV56799491; called by muse, mutect2, varscan2
- CLIP3 | c.1259A>G p.D420G | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1382364989, COSV53324278; called by muse, mutect2, varscan2
- CLSTN3 | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs769640907, COSV56935057; called by muse, mutect2, varscan2
- CNKSR1 | c.2125C>A p.L709M (on ENST00000374253 / NM_001297647.2; = p.L702M on NM_006314.3) | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); catalogued as COSV58792669; called by muse, mutect2, varscan2
- CNP | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV66367773; called by muse, mutect2, varscan2
- CNTN5 | c.2656A>C p.S886R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV54294747, COSV54318234, COSV99678233; called by muse, mutect2, varscan2
- CNTN6 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63166535; called by muse, mutect2, varscan2
- CNTNAP1 | c.2785G>T p.G929C | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99226486; called by muse, mutect2
- CNTNAP2 | c.1481A>G p.E494G | Missense Mutation (SNP) | VAF 49/58 reads (84%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62159620; called by muse, mutect2, varscan2
- CNTNAP5 | c.2146G>A p.G716R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV70479487; called by muse, mutect2, varscan2
- COBLL1 | c.427G>T p.A143S (on ENST00000392717; = p.A105S on NM_014900.5) | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); catalogued as COSV99527984; called by muse, mutect2
- COIL | c.485del p.N162Tfs*47 | Frame Shift Del (DEL) | VAF 26/128 reads (20%) | catalogued as rs769265872; called by mutect2, varscan2
- COL15A1 | c.3371G>A p.G1124E | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66642786, COSV66644676; called by muse, mutect2, varscan2
- COL27A1 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV61924011; called by muse, mutect2, varscan2
- COL4A5 | c.3530C>A p.P1177Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as rs759897999, COSV60358739; called by muse, mutect2
- COL7A1 | c.8635C>T p.P2879S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as rs771286848, COSV56476239; called by muse, mutect2, varscan2
- COL9A1 | c.848del p.P283Lfs*45 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | catalogued as rs941174282; called by mutect2, pindel, varscan2
- COL9A3 | c.1580A>G p.E527G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV58983871, COSV58986925; called by muse, mutect2, varscan2
- COLEC11 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs749339651, CD164661, COSV52592514; called by muse, mutect2, varscan2
- COLGALT2 | c.458G>C p.R153P | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.646); catalogued as COSV62728112; called by muse, mutect2, varscan2
- COLQ | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67524350; called by muse, mutect2, varscan2
- COPS2 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV54644677; called by muse, mutect2, varscan2
- CPAMD8 | c.3153del p.H1052Ifs*127 (on ENST00000651564; = p.H1005Ifs*127 on NM_015692.5) | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs750161916, COSV71597321; called by mutect2, pindel, varscan2
- CPE | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1467639638, COSV101291591; called by mutect2, varscan2
- CPEB4 | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV54170767; called by muse, mutect2, varscan2
- CPLANE1 | c.8302C>T p.R2768C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs758569421, COSV57056033; called by muse, mutect2
- CR1L | c.584del p.K195Rfs*56 | Frame Shift Del (DEL) | VAF 36/145 reads (25%) | catalogued as COSV54331368; called by mutect2, pindel, varscan2
- CR2 | c.2897C>T p.A966V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs1193574112, COSV100889719, COSV65505871; called by muse, mutect2, varscan2
- CRHR1 | c.568G>A p.A190T (on ENST00000398285 / NM_001145146.2; = p.A161T on NM_004382.5) | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.094); catalogued as rs767597712, COSV53277026; called by muse, varscan2
- CRHR1 | c.586G>A p.A196T (on ENST00000398285 / NM_001145146.2; = p.A167T on NM_004382.5) | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.044); catalogued as rs779953398, COSV53277034; called by muse, varscan2
- CRIP1 | c.125del p.G42Afs*? | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | catalogued as COSV57636068; called by mutect2, pindel, varscan2
- CROT | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs764481627, COSV58973400; called by muse, mutect2, varscan2
- CRYBB1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs745344551, COSV53232570; called by muse, mutect2, varscan2
- CRYGA | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs766174390, COSV58016099; called by muse, mutect2, varscan2
- CSNK2A1 | c.26C>A p.A9D | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99424432; called by muse, mutect2
- CSPP1 | c.1579G>A p.A527T (on ENST00000676605; = p.A486T on NM_024790.6) | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs374214705; called by muse, mutect2, varscan2
- CSRNP3 | c.1243G>A p.G415S | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.162); catalogued as COSV58776618; called by muse, mutect2, varscan2
- CTTNBP2 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs776837687, COSV50392883; called by muse, mutect2, varscan2
- CUBN | c.8443A>G p.T2815A | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as rs763687345, COSV64711381; called by muse, mutect2, varscan2
- CYP2D6 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs267608311, COSV100637316; called by muse, varscan2
- DAB1 | c.1739A>G p.D580G (on ENST00000371231; = p.D547G on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as COSV64691638; called by muse, mutect2, varscan2
- DACH2 | c.411C>G p.I137M | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64164808; called by muse, mutect2, varscan2
- DAGLA | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs996254996, COSV57194975; called by muse, mutect2, varscan2
- DAPK1 | c.4220G>A p.G1407D | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV63786112; called by muse, mutect2
- DBT | c.1352A>G p.D451G | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64497206; called by muse, mutect2, varscan2
- DCAF12L1 | c.545T>A p.L182Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64421407; called by muse, mutect2, varscan2
- DCAF12L2 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV63580758, COSV63582325; called by muse, mutect2, varscan2
- DCTN1 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.079); catalogued as COSV62619949; called by muse, mutect2, varscan2
- DCTN4 | c.1172T>C p.I391T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs753890745, COSV69781956; called by muse, mutect2, varscan2
- DDX24 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV58212075; called by muse, mutect2, varscan2
- DDX3X | c.292C>T p.R98C (on ENST00000399959; = p.R99C on NM_001356.5) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs1479548397, COSV67863277; called by muse, mutect2, varscan2
- DDX54 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58372622; called by muse, mutect2, varscan2
- DDX58 | c.830T>G p.I277R | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV65882748; called by muse, mutect2, varscan2
- DENND3 | c.2233C>A p.L745M | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52801679, COSV52804284; called by muse, mutect2, varscan2
- DEPDC7 | c.628C>T p.R210C (on ENST00000241051 / NM_001077242.2; = p.R201C on NM_139160.2) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749658035, COSV53806174, COSV53807601; called by muse, mutect2, varscan2
- DES | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.993); catalogued as rs1168604493, COSV64660072; called by muse, mutect2, varscan2
- DGKE | c.208C>A p.Q70K | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52349286; called by muse, mutect2, varscan2
- DGKZ | c.854G>T p.G285V (on ENST00000454345 / NM_001105540.2; = p.G96V on NM_003646.4) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV58986524; called by muse, mutect2, varscan2
- DHX35 | c.982T>C p.F328L | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52668902; called by muse, mutect2, varscan2
- DHX58 | c.1685C>A p.A562D | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.316); catalogued as COSV52425046; called by muse, mutect2, varscan2
- DIP2A | c.4325C>T p.T1442I | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.728); catalogued as COSV59474901; called by muse, mutect2, varscan2
- DISC1 | c.801T>G p.S267R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV54403629; called by muse, mutect2, varscan2
- DISC1 | c.2051G>T p.C684F | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV64094067; called by muse, mutect2, varscan2
- DLGAP3 | c.2893G>A p.A965T | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52392617; called by muse, mutect2, varscan2
- DLX3 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101460580, COSV71547576; called by muse, mutect2, varscan2
- DMD | c.1248A>C p.E416D | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55861310, COSV99927893; called by muse, mutect2, varscan2
- DMXL1 | c.8246G>T p.R2749I | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60707947; called by muse, mutect2, varscan2
- DMXL2 | c.2651G>A p.R884H | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.744); catalogued as rs771086816, COSV51842930; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH10 | c.9874A>G p.S3292G (on ENST00000409039; = p.S3231G on NM_207437.3) | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68990552; called by muse, mutect2, varscan2
- DNAH11 | c.1930C>T p.R644* | Nonsense Mutation (SNP) | VAF 47/86 reads (55%) | catalogued as rs1228238442, COSV60937043; called by muse, mutect2, varscan2
- DNAH12 | c.469+2T>C p.X157_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV60856233; called by muse, mutect2
- DNAH17 | c.6121C>T p.R2041W | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1316387389, COSV67762988; called by muse, mutect2, varscan2
- DNAH17 | c.6028C>A p.L2010M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101102426; called by muse, mutect2, varscan2
- DNAJC12 | c.232T>G p.W78G | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56547338; called by muse, mutect2, varscan2
- DNAJC22 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757463642, COSV67711575; called by muse, mutect2, varscan2
- DNASE1 | c.552C>T p.D184= | Splice Region (SNP) | VAF 33/148 reads (22%) | catalogued as rs769436738, COSV55912909; called by muse, mutect2, varscan2
- DNM1 | c.778C>A p.L260I | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV57850114; called by muse, mutect2, varscan2
- DPYSL4 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58306644; called by muse, mutect2
- DQX1 | c.1849A>C p.T617P | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52045522; called by muse, mutect2, varscan2
- DRC7 | c.1822G>A p.V608M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.632); catalogued as COSV61053195; called by muse, mutect2, varscan2
- DRICH1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.069); catalogued as rs750800958, COSV58503402; called by muse, mutect2, varscan2
- DSCAML1 | c.6104C>T p.A2035V (on ENST00000321322; = p.A1975V on NM_020693.4) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.079); catalogued as rs777851211; called by muse, mutect2
- DSCAML1 | c.754G>A p.A252T (on ENST00000321322; = p.A192T on NM_020693.4) | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs142110596, COSV58389573; called by muse, mutect2, varscan2
- DST | c.14387C>T p.A4796V (on ENST00000361203 / NM_001374722.1; = p.A2384V on NM_015548.5) | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs1179938274, COSV55005163; called by muse, mutect2, varscan2
- DSTN | c.308del p.L103Cfs*6 | Frame Shift Del (DEL) | VAF 17/84 reads (20%) | catalogued as rs750962255; called by mutect2, varscan2
- DZIP3 | c.3040C>T p.P1014S | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV64311556; called by muse, mutect2, varscan2
- E2F1 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs531113927, COSV55775380; called by mutect2, varscan2
- E4F1 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs868100576, COSV57038338; called by muse, mutect2
- EDAR | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764390189, COSV51501293; called by muse, mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- EEF1A2 | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53205373; called by muse, mutect2, varscan2
- EEPD1 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs746320616, COSV54196153; called by muse, mutect2, varscan2
- EFCAB5 | c.4154C>T p.A1385V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs368739349; called by muse, mutect2, varscan2
- EFHD1 | c.376del p.Q126Rfs*6 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs760712775, COSV51135066; called by mutect2, varscan2
- ELAPOR1 | c.1867del p.T623Lfs*5 | Frame Shift Del (DEL) | VAF 34/203 reads (17%) | catalogued as rs1437113456; called by mutect2, pindel, varscan2
- ELOA2 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55296134; called by muse, mutect2, varscan2
- EML3 | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.886); catalogued as rs1371104681, COSV53881797; called by muse, mutect2, varscan2
- EMSY | c.3889G>A p.A1297T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.022); catalogued as COSV58258600; called by mutect2, varscan2
- ENAH | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.005); catalogued as rs935322209, COSV52866471; called by muse, varscan2
- ENGASE | c.1402C>T p.R468W | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs369232286, COSV100285726; called by muse, mutect2, varscan2
- ENKUR | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV58632760; called by mutect2, varscan2
- ENPP2 | c.836T>C p.V279A | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV50011733, COSV50016465; called by muse, mutect2, varscan2
- ENPP6 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs919101796, COSV57066895; called by muse, mutect2, varscan2
- ENPP7 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs376245774, COSV60387696; called by muse, mutect2, varscan2
- ENTPD1 | c.694T>A p.S232T | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV64600805; called by muse, mutect2, varscan2
- EP400 | c.7453C>T p.R2485* | Nonsense Mutation (SNP) | VAF 10/163 reads (6%) | catalogued as COSV57767944; called by muse, mutect2
- EPB41 | c.1946A>G p.K649R (on ENST00000343067 / NM_001166005.2; = p.K407R on NM_004437.4) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV58044108; called by muse, mutect2, varscan2
- EPHA1 | c.992-2A>G p.X331_splice | Splice Site (SNP) | VAF 5/12 reads (42%) | catalogued as COSV51969954; called by muse, mutect2, varscan2
- EPHA2 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.38); catalogued as rs1229539733, COSV64452478; called by muse, mutect2, varscan2
- EPHA4 | c.2864G>A p.G955D | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV56029335; called by muse, mutect2, varscan2
- EPHB1 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV67656911, COSV67657380; called by muse, mutect2
- EPHB4 | c.2953C>A p.P985T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV62268347; called by muse, mutect2
- EPS8 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs577790263, COSV55528983; called by muse, mutect2, varscan2
- EPYC | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV53799098; called by muse, mutect2, varscan2
- ERAP2 | c.2013-1G>A p.X671_splice | Splice Site (SNP) | VAF 22/76 reads (29%) | catalogued as COSV65939214; called by muse, mutect2, varscan2
- ERBB3 | c.3382G>A p.G1128R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.54); catalogued as rs1181827941, COSV57249265; called by muse, mutect2, varscan2
- ERCC6L2 | c.2075C>T p.S692F | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV56629420; called by muse, mutect2, varscan2
- ERGIC2 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV64111627; called by muse, mutect2, varscan2
- ESPL1 | c.4574A>T p.E1525V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV57758372; called by muse, mutect2, varscan2
- ESPN | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1241074178, COSV64704050; called by muse, mutect2
- ESRP2 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as COSV52172710; called by muse, mutect2, varscan2
- ESYT3 | c.329T>G p.I110S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs149154169, COSV56679986; called by muse, mutect2, varscan2
- ETAA1 | c.1310G>T p.R437M | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV55472515; called by muse, mutect2, varscan2
- ETV4 | c.371G>A p.C124Y | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60044015; called by muse, mutect2, varscan2
- EVC | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867240492, COSV53830752; called by muse, mutect2, varscan2
- EVI2B | c.593del p.N198Tfs*6 | Frame Shift Del (DEL) | VAF 15/152 reads (10%) | catalogued as rs765136869; called by mutect2, pindel, varscan2
- EVPL | c.1697T>C p.I566T | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as COSV56908943; called by muse, mutect2, varscan2
- EXD3 | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); catalogued as rs1156340977, COSV59805659; called by mutect2, varscan2
- EXO1 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV62216951; called by muse, mutect2, varscan2
- EXOC1 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62119537; called by muse, mutect2, varscan2
- EXOC3L4 | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs770339782, COSV66295413; called by muse, mutect2, varscan2
- EYS | c.539C>A p.S180* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as COSV60980730; called by muse, mutect2, varscan2
- F10 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.335); catalogued as rs1263735827, COSV65021145, COSV65021195; called by muse, mutect2, varscan2
- FAH | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs755234891, COSV55720695; called by muse, mutect2, varscan2
- FAM111A | c.1515dup p.A506Sfs*23 | Frame Shift Ins (INS) | VAF 39/143 reads (27%) | catalogued as rs762116864; called by mutect2, pindel, varscan2
- FAM171A1 | c.2666T>A p.I889N | Missense Mutation (SNP) | VAF 38/504 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV65314754; called by muse, mutect2
- FAM217A | c.1331T>G p.V444G | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as COSV51159362; called by muse, mutect2
- FAM228A | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV54595046; called by muse, mutect2, varscan2
- FAM83E | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs778310926, COSV54368616; called by muse, mutect2, varscan2
- FAM90A1 | c.521C>A p.S174Y | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV56711123, COSV56714444; called by muse, mutect2, varscan2
- FASTKD3 | c.428del p.K143Rfs*36 | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | catalogued as rs773607911, COSV52947201; called by mutect2, pindel, varscan2
- FAT1 | c.12245A>G p.Y4082C | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV71673125; called by mutect2, varscan2
- FAT4 | c.5104G>A p.A1702T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV67883248; called by muse, mutect2, varscan2
- FAT4 | c.14729C>A p.A4910E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV58677345; called by muse, mutect2, varscan2
- FBH1 | c.1856C>T p.A619V (on ENST00000362091 / NM_178150.3; = p.A670V on NM_032807.4) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as rs777371692, COSV62982070; called by muse, mutect2, varscan2
- FBN1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs752010116, CM154799, COSV57312825; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN2 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs766945762, COSV52503308; called by muse, mutect2, varscan2
- FBN3 | c.2259dup p.G754Rfs*69 | Frame Shift Ins (INS) | VAF 20/64 reads (31%) | catalogued as rs755836480; called by mutect2, varscan2
- FBXO32 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1159404147, COSV54890561; called by muse, mutect2, varscan2
- FDPS | c.1243T>C p.Y415H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV52738830; called by muse, mutect2, varscan2
- FECH | c.860T>G p.V287G | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50490491; called by muse, mutect2, varscan2
- FECH | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1389107704, COSV50490500; called by muse, mutect2, varscan2
- FGA | c.1953G>T p.K651N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as COSV57394570; called by muse, mutect2, varscan2
- FGD1 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV64308385; called by muse, mutect2, varscan2
- FGD4 | c.1384G>T p.G462C | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56781787; called by muse, mutect2, varscan2
- FGF14 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs987890018, COSV65935189, COSV65937383; called by muse, mutect2, varscan2
- FHOD3 | c.2842-2A>C p.X948_splice (on ENST00000359247 / NM_001281739.3; = p.X965_splice on NM_025135.5) | Splice Site (SNP) | VAF 17/51 reads (33%) | catalogued as COSV57168473; called by muse, mutect2, varscan2
- FKTN | c.731A>C p.H244P | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV56308864; called by muse, mutect2, varscan2
- FLRT2 | c.506A>C p.N169T | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1355192950, COSV58138681; called by muse, mutect2, varscan2
- FLT4 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56102729, COSV56120827; called by muse, mutect2, varscan2
- FMN2 | c.1679A>C p.K560T | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV60424426; called by muse, mutect2, varscan2
- FMN2 | c.3782G>T p.G1261V | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60424431; called by muse, mutect2, varscan2
- FOLR3 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as rs1287584454, COSV61529960; called by muse, mutect2, varscan2
- FOXO1 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs772929365, COSV65425981; called by muse, mutect2, varscan2
- FREM2 | c.1798C>A p.L600M | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.92); catalogued as rs745963596, COSV54832863; called by muse, mutect2, varscan2
- FSIP2 | c.20473+2T>A p.X6825_splice | Splice Site (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100555304; called by muse, mutect2, varscan2
- FTH1 | c.287G>T p.S96I | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as COSV56444843; called by muse, mutect2, varscan2
- FZD7 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); catalogued as COSV99636919; called by muse, mutect2
- FZD9 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.219); catalogued as rs781793071, COSV60669825; called by muse, mutect2, varscan2
- GABRB3 | c.1132A>G p.M378V | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54655760, COSV54662039; called by muse, mutect2
- GABRB3 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as rs1555368345, COSV54655786; ClinVar: uncertain significance; called by mutect2, varscan2
- GABRD | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs886818332, COSV101059544; called by muse, mutect2
- GAD2 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1366988930, COSV52153786; called by muse, mutect2, varscan2
- GALNT17 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV61154351; called by muse, mutect2, varscan2
- GALR1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.046); catalogued as rs756079511, COSV55316467; called by muse, mutect2, varscan2
- GDPGP1 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 35/150 reads (23%) | catalogued as COSV61575689; called by muse, mutect2, varscan2
- GFRAL | c.34A>C p.S12R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.202); catalogued as COSV61229828, COSV61230378; called by muse, mutect2, varscan2
- GGN | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); catalogued as rs773804497, COSV53056460; called by muse, mutect2, varscan2
- GGPS1 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.759); catalogued as COSV51396972; called by muse, mutect2, varscan2
- GIPC2 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1488814325, COSV66127627; called by muse, mutect2
- GIT1 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.024); catalogued as rs1166333111, COSV56402054; called by muse, mutect2, varscan2
- GLRA3 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as rs201620617; called by muse, mutect2, varscan2
- GLRB | c.444A>C p.E148D | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100030220, COSV52414876; called by muse, mutect2, varscan2
- GLS2 | c.1016A>G p.D339G | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as COSV57665321; called by muse, mutect2, varscan2
- GMIP | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754729901, COSV52555153; called by muse, mutect2, varscan2
- GNB1L | c.638A>G p.D213G | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV61548171; called by muse, mutect2, varscan2
- GOLGA3 | c.2141C>T p.A714V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV52628037; called by muse, mutect2, varscan2
- GOLGA6A | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs374121270; called by muse, mutect2, varscan2
- GPD2 | c.2159T>C p.V720A | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV60091347; called by muse, mutect2, varscan2
- GPHB5 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs759641700, COSV58485790; called by muse, mutect2, varscan2
- GPR1 | c.380del p.F127Sfs*2 | Frame Shift Del (DEL) | VAF 29/119 reads (24%) | catalogued as rs759796967; called by mutect2, pindel, varscan2
- GPR141 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.972); catalogued as COSV57731434, COSV57731776; called by muse, mutect2, varscan2
- GPR158 | c.3231A>C p.Q1077H | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV66267431; called by muse, mutect2, varscan2
- GPR45 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51523209; called by muse, mutect2, varscan2
- GREB1 | c.2747G>A p.G916D | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); catalogued as COSV52183593; called by muse, mutect2, varscan2
- GRIA4 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 34/121 reads (28%) | catalogued as COSV56882174; called by muse, mutect2, varscan2
- GRIN2B | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as rs1458368988, COSV74205332; called by muse, mutect2, varscan2
- GRIN2B | c.1003C>A p.L335I | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as COSV101663133, COSV74205333; called by muse, mutect2, varscan2
- GRIN2B | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772078838, COSV74204997; called by muse, mutect2, varscan2
- GRIN3A | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs867334369, COSV62450515; called by muse, mutect2, varscan2
- GRM1 | c.2335G>A p.A779T | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs745330594, COSV51120808; called by muse, mutect2, varscan2
- GSG1L | c.808G>A p.A270T (on ENST00000447459 / NM_001109763.2; = p.A115T on NM_144675.2) | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV66576758; called by muse, mutect2, varscan2
- GUCY2F | c.557C>A p.A186D | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs1215682246, COSV54300034; called by muse, mutect2, varscan2
- HADHA | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 105/401 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs761474139, COSV66106829; called by muse, mutect2, varscan2
- HADHB | c.821C>T p.T274I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as COSV58545429; called by muse, mutect2, varscan2
- HAUS3 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 21/61 reads (34%) | catalogued as COSV54722229; called by muse, mutect2, varscan2
- HBB | c.50del p.G17Afs*3 | Frame Shift Del (DEL) | VAF 17/104 reads (16%) | catalogued as CD972888, CM860029, COSV100092817; called by mutect2, pindel, varscan2
- HCAR2 | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194187180, COSV61024627; called by muse, mutect2, varscan2
- HCFC1 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1557115711, COSV60070625; called by muse, mutect2, varscan2
- HDLBP | c.3743A>G p.E1248G | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV51470039; called by muse, mutect2
- HDLBP | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.096); catalogued as rs754784308, COSV60492393; called by muse, mutect2, varscan2
- HEATR4 | c.1617T>G p.C539W | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.318); catalogued as COSV58570924; called by muse, mutect2
- HEATR5B | c.6100C>T p.R2034C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777159304, COSV51848465; called by muse, mutect2, varscan2
- HEG1 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs772039855, COSV60760817; called by muse, mutect2, varscan2
- HELB | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV56073076; called by muse, mutect2, varscan2
- HEPHL1 | c.959C>T p.T320I | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.175); catalogued as COSV59890543; called by muse, mutect2, varscan2
- HFM1 | c.4200del p.F1400Lfs*25 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs766204131; called by mutect2, pindel, varscan2
- HIC2 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs137951777; called by muse, mutect2, varscan2
- HIF3A | c.1312C>T p.R438W (on ENST00000377670 / NM_152795.4; = p.R369W on NM_022462.4) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1369188513, COSV52196852; called by muse, mutect2, varscan2
- HIP1 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs782434689, COSV61184491; called by muse, mutect2, varscan2
- HIPK1 | c.3006G>T p.Q1002H | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.965); catalogued as COSV61246886; called by muse, mutect2, varscan2
- HIPK1 | c.3286C>A p.P1096T (on ENST00000369558 / NM_001369806.1; = p.P702T on NM_181358.2) | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV61246896; called by muse, mutect2, varscan2
- HMCN1 | c.12349C>T p.R4117C | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs777001625, COSV54873921; called by muse, mutect2, varscan2
- HMGCLL1 | c.246A>C p.E82D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV51442476, COSV51451307; called by muse, mutect2, varscan2
- HMGN3 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV51514301; called by muse, mutect2, varscan2
- HNRNPA3 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101182923; called by muse, mutect2, varscan2
- HNRNPAB | c.604T>G p.F202V | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV57423440; called by muse, mutect2, varscan2
- HNRNPH2 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 35/86 reads (41%) | catalogued as COSV54508573; called by muse, mutect2, varscan2
- HOXC12 | c.754A>G p.N252D | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.2); catalogued as COSV54534774; called by muse, mutect2, varscan2
- HPX | c.284G>A p.S95N | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.258); catalogued as COSV56418847; called by muse, mutect2, varscan2
- HSD17B2 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs1260466945, COSV52275013; called by muse, mutect2, varscan2
- HSD17B4 | c.1354G>A p.A452T (on ENST00000414835 / NM_001199291.3; = p.A427T on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.061); catalogued as rs1561469945, COSV56334491; called by muse, mutect2, varscan2
- HSDL2 | c.800C>A p.P267H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV52714067; called by muse, mutect2, varscan2
- HSPA12A | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782645684, COSV65021519; called by muse, mutect2, varscan2
- HSPBP1 | c.852G>T p.E284D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99729093; called by muse, mutect2
- HSPG2 | c.4226C>T p.A1409V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.685); catalogued as rs746918802, COSV65969722; ClinVar: uncertain significance; called by muse, mutect2
- IFFO1 | c.1089dup p.R364Afs*19 (on ENST00000396840 / NM_001330324.2; = p.R367Afs*19 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 10/33 reads (30%) | catalogued as rs750779916; called by mutect2, varscan2
- IGDCC3 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs766994812, COSV60077058; called by mutect2, varscan2
- IGF1R | c.4055del p.G1352Afs*27 | Frame Shift Del (DEL) | VAF 11/98 reads (11%) | catalogued as COSV99151177; called by mutect2, pindel, varscan2
- IGF2 | c.238G>A p.A80T (on ENST00000434045 / NM_001127598.3; = p.A24T on NM_000612.6) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV56097799; called by muse, mutect2, varscan2
- IGFALS | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs755011133, COSV51905191; called by muse, mutect2, varscan2
- IGHMBP2 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs571887680, COSV54821303; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV3-15 | c.105del p.S36Pfs*18 | Frame Shift Del (DEL) | VAF 24/116 reads (21%) | catalogued as rs781984574; called by mutect2, pindel, varscan2
- IGHV3-15 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as rs540544269; called by mutect2, varscan2
- IGSF10 | c.2051C>T p.S684F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV56783109; called by muse, mutect2, varscan2
- IGSF9 | c.2303G>A p.R768H (on ENST00000368094 / NM_001135050.2; = p.R752H on NM_020789.4) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.425); catalogued as rs1557930756, COSV63639330; called by muse, mutect2
- IKZF5 | c.338A>G p.H113R | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.197); catalogued as COSV64397366; called by muse, mutect2
- IL17RD | c.1382T>C p.L461P | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477972264, COSV56336326; called by muse, mutect2, varscan2
- ILF3 | c.983G>A p.G328D | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51555403; called by muse, mutect2, varscan2
- IMPG2 | c.3138A>C p.E1046D | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51975627; called by muse, mutect2, varscan2
- INPP5B | c.2755-2A>G p.X919_splice (on ENST00000373023; = p.X839_splice on NM_005540.3 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 5/24 reads (21%) | catalogued as COSV65960077; called by muse, mutect2, varscan2
- INPP5E | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779363781, COSV65496093; called by muse, mutect2, varscan2
- INPPL1 | c.1306G>A p.V436I | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.065); catalogued as rs758142583, COSV53354324; called by muse, mutect2, varscan2
- INSR | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs556950372, COSV57160009; called by muse, mutect2, varscan2
- INTS7 | c.2050C>T p.R684* | Nonsense Mutation (SNP) | VAF 24/56 reads (43%) | catalogued as rs147974722, COSV65343975; called by muse, varscan2
- IP6K1 | c.1132C>A p.P378T | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.142); catalogued as COSV57695155; called by muse, mutect2, varscan2
- IQCC | c.1351G>T p.G451* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV52208115; called by muse, mutect2, varscan2
- IQSEC3 | c.1838C>T p.A613V (on ENST00000538872 / NM_001170738.2; = p.A310V on NM_015232.1) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV58282675; called by muse, mutect2, varscan2
- IRAK3 | c.598dup p.M200Nfs*4 | Frame Shift Ins (INS) | VAF 74/350 reads (21%) | catalogued as rs776897837; called by mutect2, varscan2
- IRF5 | c.457A>T p.M153L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV50857080; called by muse, mutect2, varscan2
- ITGA10 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1553749614, COSV65196323; called by muse, mutect2, varscan2
- ITGA2B | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 10/14 reads (71%) | catalogued as CM981073, COSV52231483, COSV52231893; called by muse, mutect2, varscan2
- ITGAX | c.1276del p.R426Afs*20 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs1316967675; called by mutect2, pindel, varscan2
- ITGB1BP1 | c.437A>G p.D146G | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53005664; called by muse, mutect2, varscan2
- ITGBL1 | c.474C>A p.H158Q | Missense Mutation (SNP) | VAF 61/240 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV66006786; called by muse, mutect2, varscan2
- ITPKB | c.2093G>A p.R698H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs771048902, COSV55259127; called by muse, mutect2, varscan2
- ITPR3 | c.7202G>T p.R2401L | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV65290982; called by muse, mutect2, varscan2
- ITSN1 | c.2489G>A p.R830H | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1028088112, COSV66082040; called by muse, mutect2
- JMJD1C | c.6075del p.E2026Kfs*45 | Frame Shift Del (DEL) | VAF 28/146 reads (19%) | catalogued as rs1226801045; called by mutect2, varscan2
- JMJD6 | c.370A>G p.T124A | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV57970937; called by muse, mutect2, varscan2
- JPH1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60609797; called by muse, mutect2, varscan2
- JPH4 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV62508199; called by muse, varscan2
- JUN | c.920A>G p.Q307R | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV64664294; called by muse, mutect2, varscan2
- JUND | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53254504; called by muse, mutect2, varscan2
- JUP | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377612199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KALRN | c.5728G>A p.A1910T (on ENST00000360013 / NM_001024660.4; = p.A213T on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV52253635; called by muse, mutect2, varscan2
- KANSL3 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62616286, COSV62625680; called by muse, mutect2, varscan2
- KAT6B | c.4862C>T p.A1621V | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV54744557; called by muse, mutect2, varscan2
- KBTBD2 | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as rs1310970811, COSV58363128; called by muse, mutect2, varscan2
- KCND2 | c.698A>G p.D233G | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58574037; called by muse, mutect2, varscan2
- KCND3 | c.1487C>A p.P496H | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.345); catalogued as COSV56177752; called by muse, mutect2, varscan2
- KCNK13 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV56411835; called by muse, mutect2
- KCNMA1 | c.670T>G p.F224V | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV54237433; called by muse, mutect2, varscan2
- KCNN3 | c.335del p.P112Lfs*64 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs753256170; called by mutect2, pindel, varscan2
- KDM4C | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV101184645, COSV67185189; called by muse, mutect2, varscan2
- KIAA0232 | c.362C>A p.S121Y | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100300742; called by muse, mutect2
- KIAA0232 | c.1973C>A p.S658Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV56924134; called by muse, mutect2, varscan2
- KIAA0232 | c.2462G>A p.S821N | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV56924144; called by muse, mutect2, varscan2
- KIAA1958 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV61722532; called by muse, mutect2, varscan2
- KIF13B | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as rs887441990, COSV72954265; called by muse, varscan2
- KIT | c.2683G>A p.A895T | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs774405431, COSV55394257; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KL | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs930217368, COSV66308271; called by muse, mutect2
- KLHDC7B | c.1504C>T p.R502W (on ENST00000395676; = p.R1143W on NM_138433.5) | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs758075611, COSV67464366; called by muse, mutect2, varscan2
- KLHDC8B | c.1017G>T p.Q339H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60411504; called by muse, mutect2, varscan2
- KLHL11 | c.1370G>A p.S457N | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.648); catalogued as rs1555622323, COSV59861682; called by muse, mutect2, varscan2
- KLK4 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 54/67 reads (81%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); catalogued as rs267605602, COSV60676011; called by muse, mutect2, varscan2
- KMT2D | c.8713C>T p.R2905C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1170466072, COSV56423542; called by muse, mutect2, varscan2
- KNDC1 | c.3887G>A p.R1296H | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs752992378, COSV58830841, COSV58831313; called by muse, mutect2, varscan2
- KPRP | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs1461205898, COSV64221298, COSV64223224; called by muse, mutect2, varscan2
- KRT24 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52879912; called by muse, mutect2, varscan2
- KRT24 | c.110del p.G37Afs*16 | Frame Shift Del (DEL) | VAF 24/124 reads (19%) | catalogued as rs772344547, COSV99232217; called by mutect2, pindel, varscan2
- KRT28 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as rs765166901, COSV60684554; called by muse, mutect2, varscan2
- KRT6A | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV58104431; called by muse, mutect2, varscan2
- KRT6B | c.395del p.P132Lfs*14 | Frame Shift Del (DEL) | VAF 23/167 reads (14%) | catalogued as rs772129177; called by mutect2, pindel, varscan2
- KRT6C | c.1193T>C p.V398A | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.38); catalogued as COSV52877104; called by muse, mutect2, varscan2
- L1CAM | c.3461A>C p.K1154T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62827421; called by muse, mutect2, varscan2
- LAMA3 | c.4547C>T p.A1516V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as rs759552468, COSV58065645; called by muse, mutect2, varscan2
- LAMB4 | c.3434G>T p.G1145V | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs761675717, COSV52716257; called by muse, mutect2, varscan2
- LAMC2 | c.2380C>T p.R794C | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as rs1006392392, COSV51453845; called by muse, mutect2, varscan2
- LAMC3 | c.471G>A p.W157* | Nonsense Mutation (SNP) | VAF 30/142 reads (21%) | catalogued as COSV63089705; called by muse, mutect2, varscan2
- LCT | c.2218T>C p.S740P | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV51546332; called by muse, mutect2, varscan2
- LDHA | c.358A>C p.I120L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV57039211; called by muse, mutect2, varscan2
- LDHB | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as rs145369309; called by muse, mutect2, varscan2
- LDLRAP1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776857764, COSV65473137; called by muse, mutect2, varscan2
- LENG8 | c.1459C>A p.P487T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV58726817; called by muse, mutect2
- LEO1 | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs751561202, COSV55175183, COSV55176232; called by muse, mutect2, varscan2
- LGR6 | c.2840G>A p.G947D (on ENST00000367278 / NM_001017403.1; = p.G895D on NM_021636.3) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV55154085; called by muse, mutect2, varscan2
- LIG3 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52005519; called by muse, mutect2, varscan2
- LINGO2 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58058367, COSV58058499; called by muse, mutect2, varscan2
- LMO3 | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53781723; called by muse, mutect2
- LMTK2 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51992927; called by muse, mutect2, varscan2
- LRP1B | c.10132G>T p.G3378* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as COSV67200356, COSV67274347; called by muse, mutect2, varscan2
- LRP1B | c.2650C>A p.H884N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV63341674; called by muse, mutect2, varscan2
- LRP5 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.327); catalogued as rs765147716, COSV53713325, COSV99591418; called by muse, mutect2
- LRRC14B | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV99723007; called by muse, mutect2
- LRRC4 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs369606572, COSV50813485; called by muse, varscan2
- LRRC56 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs766388739, COSV54239444; called by muse, mutect2, varscan2
- LRRC8D | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV61578252; called by muse, mutect2, varscan2
- LRRIQ1 | c.4216T>A p.W1406R | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67827865; called by muse, mutect2, varscan2
- LRRIQ1 | c.4821A>C p.E1607D | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV67827870; called by muse, mutect2, varscan2
- LRRK2 | c.4915del p.R1639Gfs*15 | Frame Shift Del (DEL) | VAF 24/96 reads (25%) | catalogued as rs756089224; called by mutect2, varscan2
- LRRTM4 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as COSV69139465; called by muse, mutect2, varscan2
- LTBP1 | c.3334T>C p.S1112P (on ENST00000404816 / NM_206943.4; = p.S786P on NM_000627.4) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55377424; called by muse, mutect2, varscan2
- LZTS3 | c.1808G>A p.R603H (on ENST00000329152; = p.R557H on NM_001282533.2) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.034); catalogued as rs755335789, COSV53905046; called by muse, mutect2
- MAB21L2 | c.437G>T p.R146L | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as rs369400322; called by muse, mutect2, varscan2
- MAD2L1 | c.32T>A p.I11N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56636743; called by muse, mutect2, varscan2
- MAGEB6B | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69689822; called by muse, mutect2, varscan2
- MAGEE1 | c.1277C>A p.P426H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV63909368; called by muse, mutect2, varscan2
- MAGI2 | c.395A>G p.N132S | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62642534; called by muse, mutect2, varscan2
- MANBA | c.533T>C p.V178A | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.16); catalogued as rs762482379, COSV56964048; called by muse, mutect2, varscan2
- MAP3K6 | c.2544del p.F849Sfs*143 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | catalogued as rs34008139, CD1410625; called by mutect2, pindel, varscan2
- MATN4 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | PolyPhen probably damaging (0.999); catalogued as COSV59213093; called by muse, mutect2, varscan2
- MBNL2 | c.340-1G>A p.X114_splice | Splice Site (SNP) | VAF 12/59 reads (20%) | catalogued as COSV59119289; called by muse, mutect2
- MBTPS1 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375432685; called by muse, mutect2, varscan2
- MCC | c.1266G>T p.E422D | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.82); catalogued as COSV56726725; called by muse, mutect2, varscan2
- MCF2L | c.1679G>T p.R560M (on ENST00000375608; = p.R528M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV65049644; called by muse, mutect2, varscan2
- MDH1B | c.678G>T p.E226D | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.358); catalogued as COSV65588983; called by muse, mutect2, varscan2
- MDM2 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.746); catalogued as rs755256189, COSV50698395; called by muse, mutect2, varscan2
- MDN1 | c.6291T>A p.D2097E | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65519363; called by muse, mutect2, varscan2
- MDN1 | c.4488del p.G1497Afs*10 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | catalogued as rs1275568383, COSV101021912; called by mutect2, pindel, varscan2
- MED8 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.137); catalogued as rs767734860, COSV51940413; called by muse, mutect2, varscan2
- MEGF10 | c.1949G>A p.G650D | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57247232; called by muse, mutect2, varscan2
- MEGF8 | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as COSV52079126; called by muse, mutect2, varscan2
- MELTF | c.1337A>G p.D446G | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV56380134; called by muse, mutect2, varscan2
- MFN2 | c.803A>C p.E268A | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52421326; called by muse, mutect2, varscan2
- MGAT5B | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.125); catalogued as COSV56927256; called by muse, mutect2, varscan2
- MGAT5B | c.1621G>A p.A541T (on ENST00000569840 / NM_001199172.2; = p.A539T on NM_144677.3) | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs1555600686, COSV56927276; called by muse, mutect2, varscan2
- MICAL2 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs529390817, COSV56318423; called by muse, mutect2, varscan2
- MICAL2 | c.3304G>A p.A1102T | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.452); catalogued as rs148517207; called by muse, mutect2, varscan2
- MID1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs998633414, COSV58192655; called by muse, mutect2, varscan2
- MIDEAS | c.106del p.Q36Sfs*6 | Frame Shift Del (DEL) | VAF 13/94 reads (14%) | catalogued as COSV54098507; called by mutect2, pindel, varscan2
- MIEF1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs368491896, COSV57477780; called by muse, mutect2, varscan2
- MLST8 | c.911T>A p.I304N | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.135); catalogued as COSV57027255; called by muse, mutect2, varscan2
- MLXIPL | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs782609622, COSV57667456; called by muse, mutect2
- MMP16 | c.1534A>C p.N512H | Missense Mutation (SNP) | VAF 82/101 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54157082; called by muse, mutect2, varscan2
- MMRN1 | c.2183T>C p.L728P | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53335470; called by muse, mutect2, varscan2
- MMS22L | c.2121G>T p.E707D | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99246978; called by muse, mutect2, varscan2
- MNT | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs751790336, COSV51511524; called by muse, mutect2
- MOCOS | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.309); catalogued as rs201906396, COSV54342184; called by muse, mutect2, varscan2
- MOCS1 | c.204G>T p.Q68H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV57934553; called by muse, mutect2, varscan2
- MOGS | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV51968719; called by muse, mutect2, varscan2
- MPST | c.689G>A p.R230H (on ENST00000341116 / NM_001369904.2; = p.R250H on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs746971551, COSV62017412; called by muse, mutect2, varscan2
- MRI1 | c.901C>T p.P301S (on ENST00000040663 / NM_001031727.4; = p.P254S on NM_032285.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.241); catalogued as COSV50003941; called by muse, mutect2, varscan2
- MROH2B | c.8T>G p.L3R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV68182454; called by muse, mutect2, varscan2
- MRPL13 | c.472T>C p.Y158H | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1331941394, COSV60366992; called by muse, mutect2
- MRPL27 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.896); catalogued as rs750648679, COSV56811922; called by muse, mutect2, varscan2
- MS4A15 | c.700G>A p.A234T (on ENST00000405633 / NM_001098835.2; = p.A141T on NM_152717.3) | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs868095180, COSV61961017; called by muse, mutect2, varscan2
- MSN | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64303637; called by muse, mutect2, varscan2
- MSS51 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as COSV55018870; called by muse, mutect2, varscan2
- MTHFD2L | c.785A>G p.D262G (on ENST00000395759 / NM_001144978.2; = p.D204G on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57466575; called by muse, mutect2, varscan2
- MTOR | c.7017-1G>T p.X2339_splice | Splice Site (SNP) | VAF 30/122 reads (25%) | catalogued as COSV63869538; called by muse, mutect2, varscan2
- MTX2 | c.35T>C p.I12T | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs745769736, COSV50887647; called by muse, mutect2, varscan2
- MUC16 | c.34574C>A p.P11525H | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.212); catalogued as COSV67455107; called by muse, mutect2, varscan2
- MUC16 | c.29891G>T p.G9964V | Missense Mutation (SNP) | VAF 131/186 reads (70%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.065); catalogued as COSV67455116; called by muse, varscan2
- MUC16 | c.9834G>T p.L3278F | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV67455124; called by muse, mutect2, varscan2
- MUC5AC | c.1109C>A p.A370D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.3); catalogued as COSV62253612; called by muse, mutect2, varscan2
- MVP | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs755247776, COSV62421683; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYBPH | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs1268283195, COSV55141850; called by muse, mutect2, varscan2
- MYCL | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs748297163, COSV65693164; called by muse, mutect2, varscan2
- MYO18B | c.7235C>A p.A2412D | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV59129582; called by muse, mutect2, varscan2
- MYO3A | c.2718C>T p.G906= | Splice Region (SNP) | VAF 14/58 reads (24%) | catalogued as rs1239496761, COSV56331480; called by muse, mutect2
- NAALADL2 | c.2292A>C p.E764D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs549849310, COSV71984133; called by muse, mutect2, varscan2
- NARF | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as COSV59111119; called by muse, mutect2, varscan2
- NAV1 | c.481del p.L161Wfs*33 | Frame Shift Del (DEL) | VAF 13/28 reads (46%) | catalogued as rs1346393455; called by mutect2, pindel, varscan2
- NBEAL2 | c.6232T>C p.Y2078H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318184244, COSV52755825; called by muse, mutect2, varscan2
- NCAPG | c.977T>G p.I326S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52269320; called by muse, mutect2, varscan2
- NDST1 | c.2225C>T p.S742L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs977524041, COSV55785793; called by muse, mutect2, varscan2
- NEB | c.4939G>A p.A1647T | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs566604130, COSV50898584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEB | c.2907G>T p.M969I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV99423675; called by muse, mutect2, varscan2
- NECTIN4 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs769388890, COSV63511882; called by muse, mutect2
- NETO2 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs772817589, COSV57452814; called by muse, mutect2, varscan2
- NFASC | c.2047G>A p.G683S (on ENST00000339876 / NM_001378329.1; = p.G679S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); catalogued as rs773998845, COSV58362309; called by muse, mutect2, varscan2
- NFATC2 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.742); catalogued as rs374413124; called by muse, mutect2, varscan2
- NKX2-4 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.095); catalogued as COSV61085036; called by muse, mutect2, varscan2
- NLGN1 | c.88A>G p.T30A | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV64327484; called by muse, mutect2, varscan2
- NLGN4X | c.2401G>A p.G801R | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1279601653, COSV52010486; called by muse, mutect2, varscan2
- NLRC4 | c.2950G>A p.V984I | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.113); catalogued as COSV50872145; called by muse, mutect2, varscan2
- NLRP10 | c.326T>C p.L109P | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV60779527; called by muse, mutect2, varscan2
- NLRP5 | c.3151G>A p.A1051T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as rs374153940; called by muse, mutect2, varscan2
- NOD1 | c.1903C>A p.L635M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV56111529; called by muse, mutect2, varscan2
- NOMO1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs1394991111, COSV99814561; called by mutect2, varscan2
- NOS1 | c.3214G>C p.E1072Q | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.93); catalogued as COSV57609281; called by muse, mutect2, varscan2
- NOS1 | c.85G>T p.G29* | Nonsense Mutation (SNP) | VAF 21/94 reads (22%) | catalogued as COSV57609290, COSV57620593; called by muse, mutect2, varscan2
- NOS1AP | c.1195C>A p.L399M | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.145); catalogued as rs1240465587, COSV62633336; called by muse, mutect2, varscan2
- NOTCH2 | c.7337G>T p.G2446V | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.086); catalogued as rs375049462, COSV99077023; called by muse, mutect2, varscan2
- NOTCH2 | c.3437G>A p.C1146Y | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56686790; called by muse, mutect2, varscan2
- NOTCH2 | c.1192C>T p.Q398* | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as COSV56686799; called by muse, mutect2, varscan2
- NOTCH3 | c.5837C>T p.A1946V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54630364; called by muse, mutect2, varscan2
- NOTCH3 | c.3584del p.P1195Qfs*77 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | catalogued as COSV54625947; called by mutect2, pindel, varscan2
- NOVA1 | c.476A>C p.K159T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as COSV99947738; called by muse, mutect2, varscan2
- NPAS4 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 40/137 reads (29%) | catalogued as COSV60649583; called by muse, mutect2, varscan2
- NPC1L1 | c.3488G>A p.R1163H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.911); catalogued as rs767241752, COSV56923615; called by muse, mutect2, varscan2
- NPHP4 | c.1880C>T p.T627M | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as rs199891059, CM051573, COSV65394073; ClinVar: uncertain significance; called by muse, varscan2
- NPHS1 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as rs769782457, COSV62287051; called by muse, mutect2, varscan2
- NPL | c.166C>A p.L56M | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.462); catalogued as COSV99277579; called by muse, mutect2, varscan2
- NR1D1 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.053); catalogued as rs200286440, COSV52841696; called by muse, mutect2, varscan2
- NR1H3 | c.601del p.Q201Kfs*13 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | catalogued as rs779801455; called by mutect2, pindel, varscan2
- NR3C2 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV60987580, COSV60994994; called by muse, mutect2, varscan2
- NR4A3 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58244189; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs776154715; called by mutect2, varscan2
- NRP1 | c.1452G>A p.W484* | Nonsense Mutation (SNP) | VAF 22/155 reads (14%) | catalogued as COSV55162820; called by muse, mutect2, varscan2
- NRP2 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55925737; called by muse, mutect2, varscan2
- NRXN1 | c.4117G>T p.G1373C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV60490317; called by muse, mutect2
- NRXN2 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.797); catalogued as COSV55450270; called by muse, mutect2, varscan2
- NSUN2 | c.1972G>A p.V658M | Missense Mutation (SNP) | VAF 77/302 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs770178867, COSV52953305; called by muse, mutect2, varscan2
- NTRK2 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.428); catalogued as COSV52858481; called by muse, mutect2, varscan2
- NUDT19 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs371407959; called by muse, mutect2, varscan2
- NUMA1 | c.3551C>T p.A1184V | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.154); catalogued as rs1447517327, COSV61184255; called by muse, mutect2, varscan2
- NUMBL | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV53284752; called by muse, mutect2, varscan2
- NUP188 | c.2476C>G p.R826G | Missense Mutation (SNP) | VAF 64/269 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65361050, COSV65363650; called by muse, mutect2, varscan2
- NUP188 | c.3389G>A p.R1130H | Missense Mutation (SNP) | VAF 82/376 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs756380420, COSV65361062; called by muse, varscan2
- NYX | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61180475, COSV61181643; called by muse, mutect2, varscan2
- OBI1 | c.1839del p.L614Sfs*9 | Frame Shift Del (DEL) | VAF 22/114 reads (19%) | catalogued as rs1320199922; called by mutect2, pindel, varscan2
- OBSCN | c.15343C>T p.P5115S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV52755428, COSV52756516; called by muse, mutect2, varscan2
- OCRL | c.1841G>T p.W614L | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63980558; called by muse, mutect2, varscan2
- OGDHL | c.671A>G p.K224R | Missense Mutation (SNP) | VAF 76/313 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs780052849, COSV65101696, COSV65103551; called by muse, mutect2, varscan2
- OPTN | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs774245711, COSV53810211; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- OR10K2 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59220738; called by muse, mutect2
- OR10Z1 | c.850del p.L284Sfs*9 | Frame Shift Del (DEL) | VAF 64/351 reads (18%) | catalogued as rs745317170; called by mutect2, pindel, varscan2
- OR13H1 | c.757T>C p.S253P | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV58547276; called by muse, mutect2, varscan2
- OR2L2 | c.451A>C p.S151R | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs762091199, COSV63550275, COSV63565044; called by muse, mutect2, varscan2
- OR2T35 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100442284; called by mutect2, varscan2
- OR2T8 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs1292587547, COSV100178478, COSV60662050; called by muse, varscan2
- OR2V2 | c.902C>A p.A301E | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769091130, COSV60315048; called by muse, mutect2, varscan2
- OR4C46 | c.404A>C p.N135T | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as COSV60218712; called by muse, mutect2, varscan2
- OR4F15 | c.856A>G p.I286V | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.226); catalogued as rs1161921371, COSV59968644; called by muse, mutect2
- OR52N1 | c.28A>T p.T10S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV57693106; called by muse, mutect2, varscan2
- OR5J2 | c.712T>G p.F238V | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56620520; called by muse, mutect2, varscan2
- OR5M3 | c.304T>G p.F102V | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV56566196; called by muse, mutect2, varscan2
- OR5M3 | c.169A>G p.M57V | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs1462869751, COSV56566206; called by muse, mutect2, varscan2
- OR5P2 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV61490183; called by muse, mutect2, varscan2
- OR6C1 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 20/87 reads (23%) | catalogued as COSV65573006; called by muse, mutect2, varscan2
- OR9G1 | c.908T>G p.L303R | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100380420; called by muse, mutect2, varscan2
- OR9K2 | c.978del p.K326Nfs*3 (on ENST00000305377; = p.K304Nfs*3 on NM_001005243.1) | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | catalogued as rs1249976011; called by mutect2, pindel, varscan2
- ORAI3 | c.115A>G p.M39V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as COSV57941542; called by muse, mutect2, varscan2
- OSGIN2 | c.1369G>T p.A457S | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV52407722; called by muse, mutect2, varscan2
- OTOA | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs149668552; called by muse, mutect2, varscan2
- OTUD4 | c.2909G>C p.R970T (on ENST00000447906 / NM_001366057.1; = p.R905T on NM_001102653.1) | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.083); catalogued as COSV71381608; called by muse, mutect2
- P2RX7 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 74/293 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs200108827; called by muse, mutect2, varscan2
- PACSIN3 | c.339G>A p.W113* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as rs1215762904, COSV54065558; called by muse, mutect2, varscan2
- PADI3 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs975519656, COSV64934166; called by muse, mutect2
- PAK4 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs780795083, COSV58944417; called by muse, mutect2, varscan2
- PAK6 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs778995699, COSV53044935; called by muse, mutect2, varscan2
- PALMD | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.207); catalogued as rs556174782, COSV54163638; called by muse, mutect2, varscan2
- PAMR1 | c.232T>C p.S78P | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as COSV53510905; called by muse, mutect2, varscan2
- PASK | c.2940del p.K981Rfs*22 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | catalogued as rs768409016; called by mutect2, pindel, varscan2
- PATJ | c.3782G>A p.R1261H | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1439828166, COSV56248426; called by muse, mutect2, varscan2
- PATJ | c.4280C>T p.T1427M | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as rs781480188, COSV56248445; called by muse, mutect2, varscan2
- PAX6 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV53792520; called by muse, mutect2, varscan2
- PCDH12 | c.1491C>G p.Y497* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as COSV51520355; called by muse, mutect2, varscan2
- PCDH8 | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV58811481; called by muse, varscan2
- PCDHA1 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as COSV65372518; called by muse, mutect2, varscan2
- PCDHA12 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.435); catalogued as rs1554168978, COSV56488024; called by muse, mutect2, varscan2
- PCDHA13 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV56477337; called by muse, mutect2, varscan2
- PCDHB4 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52021012; called by muse, mutect2, varscan2
- PCDHB7 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50758859; called by muse, mutect2, varscan2
- PCDHB9 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.132); catalogued as rs782490536, COSV53377046; called by muse, mutect2, varscan2
- PCDHGA11 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 80/330 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53919784; called by muse, mutect2, varscan2
- PCDHGA4 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.011); catalogued as rs1339855222, COSV53919724; called by muse, mutect2, varscan2
- PCDHGA5 | c.2137G>A p.V713M | Missense Mutation (SNP) | VAF 70/269 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.438); catalogued as COSV53919738, COSV53920540; called by muse, mutect2, varscan2
- PCDHGA7 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs751472631, COSV53919764; called by muse, mutect2, varscan2
- PCDHGB3 | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs548499010, COSV53919749; called by muse, mutect2, varscan2
- PCDHGC4 | c.1930G>A p.V644I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.759); catalogued as rs1348297963, COSV52746226, COSV52747117; called by muse, mutect2, varscan2
- PCIF1 | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs769011759, COSV59816841; called by muse, mutect2, varscan2
- PCK1 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs747438321, COSV60126288; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCNX2 | c.457T>C p.S153P | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV50788831; called by muse, mutect2, varscan2
- PCNX3 | c.2544C>T p.H848= | Splice Region (SNP) | VAF 25/97 reads (26%) | catalogued as rs756638004, COSV63135725; called by muse, mutect2, varscan2
- PDE10A | c.1595del p.T532Mfs*2 | Frame Shift Del (DEL) | VAF 44/83 reads (53%) | catalogued as COSV100605661; called by mutect2, pindel, varscan2
- PDE11A | c.498dup p.T167Hfs*34 | Frame Shift Ins (INS) | VAF 32/103 reads (31%) | catalogued as rs750496546; called by mutect2, pindel, varscan2
- PDGFRA | c.2228T>C p.V743A | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57266426; called by muse, mutect2, varscan2
- PDGFRB | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV55802869, COSV99940913; called by muse, mutect2, varscan2
- PDIA6 | c.746C>A p.P249H | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55349963, COSV99694640; called by muse, mutect2, varscan2
- PDSS1 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs762651649, COSV66058610; called by muse, mutect2, varscan2
- PDZD2 | c.3007C>T p.R1003C | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs771893787, COSV56854330; called by muse, mutect2, varscan2
- PEX1 | c.2060G>A p.R687Q | Missense Mutation (SNP) | VAF 25/302 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.145); catalogued as rs201443294; ClinVar: uncertain significance; called by muse, mutect2
- PEX16 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs375900051; called by muse, mutect2
- PEX16 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 170/311 reads (55%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs776600798, COSV53801354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PFKP | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1212418691, COSV66895835; called by muse, mutect2, varscan2
- PGAP2 | c.590C>T p.A197V (on ENST00000463452 / NM_001346398.2; = p.A258V on NM_014489.4) | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs1045801313, COSV53464548; called by muse, mutect2, varscan2
- PGR | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV54798607; called by muse, mutect2, varscan2
- PHKA2 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs995558826, COSV66053037; called by muse, mutect2, varscan2
- PHOX2B | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1338837491, COSV56928986; called by muse, mutect2, varscan2
- PHTF2 | c.1745T>C p.L582S (on ENST00000248550 / NM_001366089.1; = p.L544S on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV50324681; called by muse, mutect2, varscan2
- PIBF1 | c.33del p.V12* | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs925772654; called by mutect2, pindel, varscan2
- PIK3R1 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 34/87 reads (39%) | catalogued as rs1230037871, COSV57127263; called by muse, mutect2, varscan2
- PIK3R4 | c.876G>T p.Q292H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV63239904; called by muse, mutect2, varscan2
- PITPNM1 | c.1266G>T p.E422D | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.108); catalogued as COSV62707759; called by muse, varscan2
- PITPNM3 | c.2810C>A p.A937D | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV51470538; called by muse, mutect2, varscan2
- PKDREJ | c.4664A>G p.H1555R | Missense Mutation (SNP) | VAF 61/247 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as COSV53547648; called by muse, mutect2, varscan2
- PKN2 | c.684A>G p.I228M | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60130674; called by muse, mutect2, varscan2
945 further variants in this file (494 protein-altering or splice-affecting, 416 silent, 35 other) are not listed here.
